Somatic mutation profile of tumor specimen TCGA-AR-A1AH-01A (aliquot TCGA-AR-A1AH-01A-11D-A12B-09) from TCGA case TCGA-AR-A1AH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.0 years (18,991 days).
Specimen TCGA-AR-A1AH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90067e21-4a47-444f-92ee-27bb2a53ddf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AH-10A (Blood Derived Normal), aliquot TCGA-AR-A1AH-10A-01D-A12B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08fd8154-5f58-42a4-979c-2454a40c169c

The open-access MAF lists 99 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 26, Frame Shift Del 4, Splice Site 3, Splice Region 3, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs527660684, COSV58131161; called by muse, mutect2, varscan2
- ACAD10 | c.2588C>A p.T863N | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV58155177; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1140G>A p.L380= | Splice Region (SNP) | VAF 71/182 reads (39%) | catalogued as COSV56474665; called by muse, mutect2, varscan2
- ADRA1A | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52360029; called by muse, mutect2, varscan2
- AK9 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58140261; called by muse, mutect2, varscan2
- AMBRA1 | c.3608C>A p.T1203N (on ENST00000458649 / NM_001367468.1; = p.T1113N on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/235 reads (49%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV54051189; called by muse, mutect2, varscan2
- ASXL3 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.11); catalogued as COSV52461848; called by muse, mutect2, varscan2
- CCP110 | c.2575G>C p.V859L | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66816771; called by muse, mutect2, varscan2
- CDH6 | c.20T>G p.F7C | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV54066902; called by muse, mutect2, varscan2
- CFHR1 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 309/609 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57626654; called by muse, mutect2, varscan2
- CNTN5 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.202); catalogued as COSV99682355; called by muse, mutect2
- CNTN6 | c.359-1G>T p.X120_splice | Splice Site (SNP) | VAF 52/121 reads (43%) | catalogued as COSV63166747; called by muse, mutect2, varscan2
- CTAGE6 | c.1098G>T p.L366F | Missense Mutation (SNP) | VAF 126/606 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs752530129, COSV101417899; called by muse, mutect2, varscan2
- CYP4F11 | c.345T>A p.A115= | Splice Region (SNP) | VAF 71/153 reads (46%) | catalogued as COSV56126307; called by muse, mutect2, varscan2
- DKKL1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV55561937; called by muse, mutect2, varscan2
- DNAH17 | c.12688G>T p.V4230F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53144275; called by muse, mutect2, varscan2
- ELAPOR2 | c.2735C>A p.S912Y (on ENST00000450689 / NM_001142749.3; = p.S745Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs749291023, COSV51885344, COSV99789101; called by muse, mutect2, varscan2
- ELAPOR2 | c.1731+2T>C p.X577_splice (on ENST00000450689 / NM_001142749.3; = p.X410_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 156/353 reads (44%) | catalogued as COSV99789506; called by muse, mutect2, varscan2
- ENAH | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52866552; called by muse, mutect2, varscan2
- FAM193B | c.614del p.S205Wfs*57 | Frame Shift Del (DEL) | VAF 61/109 reads (56%) | catalogued as COSV61557599, COSV61557652; called by mutect2, pindel, varscan2
- FAM210A | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 213/511 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59183798; called by muse, mutect2, varscan2
- ING1 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.71); PolyPhen benign (0.07); catalogued as rs1421323131, COSV58168123, COSV58168406; called by muse, mutect2, varscan2
- IQCF1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 44/410 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs201110622, COSV58823471; called by muse, mutect2, varscan2
- LDHC | c.590G>C p.S197T | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV99772486, COSV99772720; called by muse, mutect2
- LRP2 | c.6635G>T p.R2212I | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.115); catalogued as COSV55547046; called by muse, mutect2, varscan2
- MDGA1 | c.2104C>A p.Q702K | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV51793710; called by muse, mutect2, varscan2
- MROH2B | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.569); catalogued as COSV68182550; called by muse, mutect2, varscan2
- MRPL20 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61224106; called by muse, mutect2, varscan2
- MUC16 | c.16778C>A p.T5593N | Missense Mutation (SNP) | VAF 159/367 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.139); catalogued as COSV67455596; called by muse, mutect2, varscan2
- MYH14 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51813595; called by muse, mutect2, varscan2
- MYH7B | c.1890+2T>C p.X630_splice | Splice Site (SNP) | VAF 36/92 reads (39%) | catalogued as COSV53417965; called by muse, mutect2, varscan2
- NDUFS2 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63487523; called by muse, mutect2, varscan2
- NEB | c.7071C>A p.F2357L | Missense Mutation (SNP) | VAF 119/285 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV50806544, COSV99415907; called by muse, mutect2, varscan2
- NR0B2 | c.157C>G p.H53D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV54259420; called by muse, mutect2, varscan2
- NSUN3 | c.900C>G p.H300Q | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58934652; called by muse, mutect2, varscan2
- OGDHL | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV65101568, COSV65103966; called by muse, mutect2
- OPRM1 | c.904G>C p.V302L | Missense Mutation (SNP) | VAF 163/570 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as COSV57674395; called by muse, mutect2, varscan2
- OSBPL1A | c.2736G>C p.E912D (on ENST00000319481 / NM_080597.4; = p.E399D on NM_018030.4) | Missense Mutation (SNP) | VAF 112/629 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as COSV59110505; called by muse, mutect2, varscan2
- OSBPL2 | c.1225C>G p.R409G (on ENST00000313733 / NM_144498.4; = p.R397G on NM_014835.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100569373, COSV58218898; called by muse, mutect2
- OTC | c.397A>G p.S133G | Missense Mutation (SNP) | VAF 229/415 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99234403; called by muse, mutect2
- PCDHA9 | c.2359G>A p.G787R | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV65324814; called by muse, mutect2, varscan2
- PDCD11 | c.3604G>T p.A1202S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV100874439; called by muse, mutect2
- PPEF1 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 158/407 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as COSV62995415; called by muse, mutect2, varscan2
- PRR19 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100004191; called by muse, mutect2
- PSG7 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs1462148959, COSV68444719; called by muse, mutect2, varscan2
- PTPRO | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55506182; called by muse, mutect2, varscan2
- PUS10 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57451315; called by muse, mutect2, varscan2
- RNF182 | c.148A>C p.K50Q | Missense Mutation (SNP) | VAF 95/368 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs574090276, COSV70368905; called by muse, mutect2, varscan2
- RPS6KA4 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53701738, COSV53701770; called by muse, mutect2, varscan2
- SCN10A | c.2655C>A p.F885L | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71860834; called by muse, mutect2, varscan2
- SIRT5 | c.618G>C p.R206= | Splice Region (SNP) | VAF 39/140 reads (28%) | catalogued as COSV63080083, COSV63081287; called by muse, mutect2, varscan2
- SYNE1 | c.16415G>T p.C5472F (on ENST00000367255 / NM_182961.4; = p.C5401F on NM_033071.3) | Missense Mutation (SNP) | VAF 133/450 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as COSV54942023; called by muse, mutect2, varscan2
- SYNE1 | c.7685T>A p.M2562K (on ENST00000367255 / NM_182961.4; = p.M2569K on NM_033071.3) | Missense Mutation (SNP) | VAF 118/657 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54942053; called by muse, mutect2, varscan2
- TIPIN | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 108/152 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV56019710; called by muse, mutect2, varscan2
- TLL1 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 175/232 reads (75%) | catalogued as COSV50268851; called by muse, mutect2, varscan2
- TLL2 | c.1820A>G p.Y607C | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63571521; called by muse, mutect2, varscan2
- TNRC6A | c.1854C>A p.N618K | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV59362567; called by muse, mutect2, varscan2
- TP53 | c.322_323del p.G108Ffs*40 | Frame Shift Del (DEL) | VAF 20/33 reads (61%) | catalogued as COSV52820923; called by mutect2, pindel, varscan2
- UGT1A10 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 225/539 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV60835012; called by muse, mutect2, varscan2
- UNC93B1 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV57098400; called by muse, mutect2, varscan2
- USH2A | c.3893A>C p.Q1298P | Missense Mutation (SNP) | VAF 129/313 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.602); catalogued as COSV56348367; called by muse, mutect2, varscan2
- VNN2 | c.165C>G p.N55K | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV58472033; called by muse, mutect2, varscan2
- WNK2 | c.4882G>C p.D1628H (on ENST00000297954 / NM_001282394.1; = p.D1591H on NM_006648.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52936900; called by muse, mutect2, varscan2
- WNT10B | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56405071; called by muse, mutect2, varscan2
- ZNF214 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53481188; called by muse, mutect2, varscan2
- CNOT10 | c.461dup p.L154Ffs*13 | Frame Shift Ins (INS) | VAF 320/516 reads (62%) | called by mutect2, pindel, varscan2
- ETHE1 | c.284_286del p.L95del | In Frame Del (DEL) | VAF 7/60 reads (12%) | called by pindel, varscan2
- GPR179 | c.7072A>G p.T2358A (on ENST00000621958; = p.T2357A on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- GPR179 | c.7071C>A p.F2357L (on ENST00000621958; = p.F2356L on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- GSE1 | c.149_156del p.L50Pfs*87 | Frame Shift Del (DEL) | VAF 9/14 reads (64%) | called by mutect2, varscan2
- PADI2 | c.628_631del p.D210Kfs*72 | Frame Shift Del (DEL) | VAF 76/107 reads (71%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.73_102del p.L25_L34del | In Frame Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- ACOT4 | c.147C>T p.H49= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs774117215, COSV58335542; called by muse, mutect2, varscan2
- ASXL2 | c.435A>G p.P145= | Silent (SNP) | VAF 253/505 reads (50%) | catalogued as COSV55456058; called by muse, mutect2, varscan2
- BANP | c.1326C>T p.F442= (on ENST00000286122; = p.F414= on NM_079837.3) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53735496; called by muse, mutect2, varscan2
- BCLAF3 | c.1602A>G p.K534= | Silent (SNP) | VAF 112/281 reads (40%) | catalogued as COSV61413504; called by muse, mutect2, varscan2
- C1orf174 | c.636T>G p.S212= | Silent (SNP) | VAF 107/334 reads (32%) | catalogued as COSV100220922; called by muse, mutect2
- CLDN23 | c.516G>T p.L172= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV67731486; called by muse, mutect2, varscan2
- CNTN1 | c.1434T>C p.D478= | Silent (SNP) | VAF 48/1296 reads (4%) | catalogued as rs1172111840, COSV100752005; called by muse, mutect2
- COL6A5 | c.6960C>T p.Y2320= (on ENST00000312481; = p.Y2316= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/170 reads (71%) | catalogued as COSV55194660, COSV55196960; called by muse, mutect2, varscan2
- FAM207A | c.303T>C p.V101= | Silent (SNP) | VAF 43/202 reads (21%) | catalogued as COSV52420075; called by muse, mutect2, varscan2
- INPP5D | c.99C>T p.S33= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs754639374, COSV64036243; called by muse, mutect2, varscan2
- ISM2 | c.378T>C p.D126= | Silent (SNP) | VAF 70/98 reads (71%) | catalogued as rs138208534; called by muse, mutect2, varscan2
- ITPR2 | c.6939A>C p.A2313= | Silent (SNP) | VAF 92/705 reads (13%) | catalogued as COSV67267010; called by muse, mutect2, varscan2
- KCNH1 | c.2535G>T p.G845= (on ENST00000271751 / NM_172362.3; = p.G818= on NM_002238.4) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV55074921, COSV55075136; called by muse, mutect2, varscan2
- L1CAM | c.3051C>A p.I1017= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV62827435; called by muse, mutect2, varscan2
- NBAS | c.4986A>T p.A1662= | Silent (SNP) | VAF 464/515 reads (90%) | catalogued as COSV55716850; called by muse, mutect2, varscan2
- OR4C15 | c.201G>C p.L67= (on ENST00000314644; = p.L13= on NM_001001920.2) | Silent (SNP) | VAF 82/193 reads (42%) | catalogued as COSV58951594, COSV58951851; called by muse, mutect2, varscan2
- PLXNA2 | c.3927C>A p.R1309= | Silent (SNP) | VAF 66/171 reads (39%) | catalogued as COSV65439155; called by muse, mutect2, varscan2
- POU3F4 | c.174G>T p.V58= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV64538251; called by muse, mutect2, varscan2
- PRKCE | c.1188G>A p.R396= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1476515682, COSV60315470; called by muse, mutect2, varscan2
- SCN4A | c.2187C>T p.C729= | Silent (SNP) | VAF 99/223 reads (44%) | catalogued as rs749942058, COSV71126161; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC27A4 | c.138C>A p.I46= | Silent (SNP) | VAF 78/102 reads (76%) | catalogued as COSV55959430; called by muse, mutect2, varscan2
- SND1 | c.2661C>T p.S887= | Silent (SNP) | VAF 220/468 reads (47%) | catalogued as rs767963514, COSV61238173; called by muse, mutect2, varscan2
- UGT2B15 | c.33G>T p.L11= | Silent (SNP) | VAF 77/110 reads (70%) | catalogued as COSV57733706; called by muse, mutect2, varscan2
- ZIM2 | c.870A>G p.R290= | Silent (SNP) | VAF 97/307 reads (32%) | catalogued as COSV55629336; called by muse, mutect2, varscan2
- ZNF598 | c.1410G>T p.P470= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs549983056, COSV70910220, COSV70910927; called by muse, varscan2
- ZNF791 | c.1035A>G p.V345= | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as COSV100589176; called by muse, mutect2, varscan2
- SUGCT | c.1090-65356G>C | Intron (SNP) | VAF 78/402 reads (19%) | catalogued as COSV59322340; called by muse, mutect2, varscan2
